Gene-level copy-number profile of specimen HCM-SANG-0532-C20-85A-01D-A80T-32 from HCMI case HCM-SANG-0532-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; Tumor grade: G2.
Specimen HCM-SANG-0532-C20-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cce21b34-4371-4ded-a767-1353c5fd31a5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0532-C20-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/e11f120e-593c-4e09-8b68-0e43f1bfdb5c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 66; copy number 2: 39,755; copy number 3: 18,546; copy number 4: 14; copy number 5: 3; copy number 6: 3; copy number 7: 4.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:59,703,606–59,703,703, 1 gene (within-gene range 0–1): MIR582.
- chr6:32,517,353–32,530,287, 1 gene: HLA-DRB5.
- chr6:32,578,769–32,589,848, 1 gene: HLA-DRB1.
- chr20:14,757,563–14,758,056, 1 gene (within-gene range 0–3): RPS10P2.
- chr20:14,933,843–14,935,363, 1 gene (within-gene range 0–3): AL138808.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:43,672,823–43,674,591, 2 genes, copy number 5: AC139365.2, AC139365.1.
- chr8:46,549,089–46,550,802, 1 gene, copy number 5: HSPA8P13.
- chr17:18,426,861–18,442,895, 2 genes, copy number 6: KRT17P2, KRT16P1.
- chr20:30,484,925–30,816,274, 4 genes, copy number 7: 5_8S_rRNA, ANKRD20A21P, U6, RNA5SP528.

Autosomal genes at a single copy (total copy number 1): 66. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
